Somatic mutation profile of tumor specimen TCGA-VQ-A91D-01A (aliquot TCGA-VQ-A91D-01A-11D-A410-08) from TCGA case TCGA-VQ-A91D, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 70.3 years (25,686 days).
Specimen TCGA-VQ-A91D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faf07e3d-302d-481c-b3c6-20351a4ffae3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91D-10A (Blood Derived Normal), aliquot TCGA-VQ-A91D-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/963db3df-c9b1-4891-8f8a-78b127472d22

The open-access MAF lists 2,766 somatic variants for this specimen: 2,084 protein-altering or splice-affecting, 620 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,468, Silent 620, Frame Shift Del 414, Frame Shift Ins 80, Nonsense Mutation 70, Splice Site 23, Intron 21, Splice Region 15, RNA 14, In Frame Del 13, 3'UTR 12, 3'Flank 5.

Variants (750 of 2,766; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALG6 | c.634del p.C212Afs*20 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs879133727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ATM | c.8122G>A p.D2708N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs587782719, CM063855, COSV53730850, COSV53785475; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CENPF | c.5920del p.T1974Pfs*11 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs757531591; ClinVar: pathogenic; called by mutect2, varscan2
- CFTR | c.2089dup p.R697Kfs*33 | Frame Shift Ins (INS) | VAF 15/39 reads (38%) | catalogued as rs397508341; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 45/132 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERF | c.879del p.S295Afs*16 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1555750642; ClinVar: likely pathogenic; called by mutect2, pindel
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 24/50 reads (48%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LMNA | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs727505038, COSV100738594; ClinVar: likely pathogenic; called by muse, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 62/100 reads (62%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYPN | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | catalogued as rs1057519573, COSV62741958; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEK1 | c.1908del p.V637Cfs*34 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs775849720; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as rs1554048066, CM1311704, COSV57191996; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCNN1B | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as rs137852704, CM941273, COSV56312145; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADACL2 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100735730; called by muse, mutect2, varscan2
- ABCA12 | c.1231C>T p.R411C (on ENST00000272895 / NM_173076.3; = p.R93C on NM_015657.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs774434795, COSV55950674; called by muse, mutect2, varscan2
- ABCA2 | c.4322G>A p.S1441N (on ENST00000614293; = p.S1411N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV99687386; called by muse, mutect2, varscan2
- ABCA3 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.264); catalogued as COSV100068281; called by muse, mutect2, varscan2
- ABCA4 | c.6250G>A p.A2084T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250914690, COSV64671514, COSV64677755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB11 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV99791886; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ABCB8 | c.1795G>A p.E599K (on ENST00000297504 / NM_001282291.2; = p.E582K on NM_007188.5) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs565354105, COSV99874171; called by muse, mutect2, varscan2
- ABCC1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746483854, COSV60683042; called by muse, mutect2, varscan2
- ABCG4 | c.1021A>G p.S341G | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100266665; called by muse, mutect2, varscan2
- ABHD8 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs756925739, COSV99395465; called by muse, mutect2, varscan2
- ABI3 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as rs771711245, COSV99865422; called by muse, varscan2
- ABL1 | c.1340A>C p.Q447P | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100583757; called by muse, mutect2, varscan2
- ABL2 | c.1535dup p.K513* (on ENST00000502732 / NM_007314.4; = p.K498* on NM_005158.5) | Frame Shift Ins (INS) | VAF 26/95 reads (27%) | catalogued as rs753365868; called by mutect2, pindel, varscan2
- ABRA | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100357514; called by muse, mutect2, varscan2
- AC005324.2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs772945975, COSV100371820; called by muse, mutect2, varscan2
- AC132217.2 | c.131T>G p.I44S | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV100323999; called by muse, mutect2, varscan2
- ACCSL | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs572708948, COSV66582505; called by muse, mutect2, varscan2
- ACOXL | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100490051; called by muse, mutect2, varscan2
- ACSBG2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.756); catalogued as COSV53123446; called by muse, mutect2, varscan2
- ACTG2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100608990; called by muse, mutect2, varscan2
- ACTL6A | c.1087A>G p.R363G | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66998626; called by muse, mutect2, varscan2
- ACTN4 | c.2345G>A p.G782D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99400018; called by muse, mutect2, varscan2
- ACTR1A | c.935A>C p.D312A | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV99487800; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 24/52 reads (46%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD1 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99635408; called by muse, mutect2, varscan2
- ADAM11 | c.104del p.G35Afs*52 | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | catalogued as rs767694891; called by mutect2, pindel, varscan2
- ADAM21 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99960784; called by muse, mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAMTS1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1379843029, COSV53171520; called by muse, mutect2
- ADAMTS5 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1292814512, COSV99537382; called by muse, mutect2, varscan2
- ADAMTS5 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.334); catalogued as COSV53185072; called by muse, varscan2
- ADAMTS5 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs969664820, COSV99537385; called by muse, varscan2
- ADAMTS9 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs772774188, COSV99899181; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4643G>A p.R1548Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as rs753552382, COSV65879539; called by muse, mutect2, varscan2
- ADARB2 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs377469652; called by muse, mutect2
- ADCK1 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs779077621, COSV99451420; called by muse, mutect2, varscan2
- ADCY2 | c.779T>C p.I260T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100602457; called by muse, mutect2, varscan2
- ADCY2 | c.3188T>C p.I1063T | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57871867; called by muse, mutect2
- ADCY4 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs777010278, COSV60252172; called by muse, mutect2, varscan2
- ADCY4 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371931557, COSV60258080; called by muse, mutect2, varscan2
- ADCY7 | c.2344G>A p.G782S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1315861352, COSV99575856; called by muse, mutect2
- ADCY8 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs780241069, COSV53906557, COSV99651887; called by muse, mutect2, varscan2
- ADD2 | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100035267; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB1 | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV100029476; called by muse, mutect2, varscan2
- ADGRV1 | c.4995G>T p.L1665F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315730; called by muse, mutect2, varscan2
- ADH4 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs111700010; called by muse, mutect2, varscan2
- ADI1 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100537735; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | catalogued as rs761350619; called by mutect2, varscan2
- ADPRM | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV101126062; called by muse, mutect2
- ADRA2A | c.1123T>C p.S375P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV54529135; called by muse, mutect2
- ADRA2A | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54526955, COSV99701732; called by muse, varscan2
- AGAP1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs143715398; called by muse, mutect2, varscan2
- AGBL5 | c.2621T>A p.V874D | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV100789512; called by muse, mutect2
- AGO1 | c.2030T>A p.I677K | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV100940803; called by muse, mutect2
- AGRN | c.1733G>C p.C578S | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101038727; called by muse, mutect2
- AGTRAP | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as COSV100065278; called by muse, mutect2, varscan2
- AHNAK2 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 70/456 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100316856; called by muse, mutect2, varscan2
- AHRR | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs373499533; called by muse, mutect2, varscan2
- AIMP2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs377537932, COSV56149646; called by muse, mutect2, varscan2
- AKR1B15 | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV101423364, COSV71153144; called by muse, mutect2, varscan2
- AKR1E2 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100033460; called by muse, mutect2, varscan2
- AKR1E2 | c.676T>G p.S226A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV100033461; called by muse, mutect2, varscan2
- AKT2 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100251534; called by muse, mutect2, varscan2
- ALDH18A1 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs755553870, COSV100973125; called by muse, mutect2, varscan2
- ALDH1B1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs770868005, COSV66620743; called by muse, mutect2
- AMDHD2 | c.630G>A p.G210= | Splice Region (SNP) | VAF 22/98 reads (22%) | catalogued as COSV99565738; called by muse, mutect2, varscan2
- AMFR | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs869025244, COSV51920574; ClinVar: uncertain significance; called by muse, varscan2
- AMPD1 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100814978; called by muse, mutect2, varscan2
- ANAPC7 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs768592404, COSV71443990; called by muse, mutect2, varscan2
- ANGPTL6 | c.1003T>C p.Y335H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV99463500; called by muse, mutect2, varscan2
- ANK3 | c.7343A>G p.Y2448C | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV99779348; called by muse, mutect2, varscan2
- ANKDD1A | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs766001684, COSV100132750, COSV60354411; called by muse, mutect2, varscan2
- ANKFN1 | c.258dup p.H87Tfs*2 | Frame Shift Ins (INS) | VAF 21/91 reads (23%) | catalogued as rs1322720501; called by mutect2, varscan2
- ANKFY1 | c.2292G>T p.E764D (on ENST00000341657 / NM_001330063.2; = p.E765D on NM_016376.5) | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100492517; called by muse, mutect2, varscan2
- ANKLE2 | c.1221del p.D408Tfs*20 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as COSV61709966; called by mutect2, pindel, varscan2
- ANKRD1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs866604612, COSV100865314; called by muse, mutect2, varscan2
- ANKRD11 | c.6547G>C p.V2183L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV56375995, COSV99968930; called by muse, mutect2, varscan2
- ANKS1A | c.2915C>T p.T972M | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319209681, COSV100832251; called by muse, mutect2, varscan2
- ANLN | c.3185G>A p.R1062Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140729544, COSV56078104; called by muse, mutect2, varscan2
- ANO9 | c.1310T>C p.I437T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100240865; called by muse, mutect2, varscan2
- ANO9 | c.896A>G p.Y299C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV100240866; called by muse, mutect2, varscan2
- ANP32A | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV51189644; called by muse, mutect2, varscan2
- ANXA2 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1043897041, COSV100221944, COSV60317731; called by muse, mutect2, varscan2
- AOC1 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100710722; called by muse, mutect2, varscan2
- AP1B1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760201939, COSV100434303; called by muse, mutect2, varscan2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs753324780, COSV52227333; called by mutect2, pindel, varscan2
- AP4M1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs146445385; called by muse, mutect2, varscan2
- APBA2 | c.1858T>A p.S620T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as COSV101258147; called by muse, mutect2, varscan2
- APEH | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1019425441, COSV56534537; called by muse, mutect2, varscan2
- APLNR | c.318C>A p.S106R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57243981, COSV99951352; called by muse, mutect2, varscan2
- APMAP | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs181867455, COSV99468412; called by muse, mutect2, varscan2
- APOBEC3B | c.1012T>C p.Y338H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100213720; called by muse, mutect2, varscan2
- AQP6 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100210138; called by muse, mutect2, varscan2
- ARAP1 | c.3133C>T p.R1045C (on ENST00000393609 / NM_001040118.2; = p.R800C on NM_015242.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs374722023, COSV61990974; called by muse, mutect2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs774148781; called by mutect2, varscan2
- ARFGEF2 | c.1256G>A p.G419D | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100904187; called by muse, mutect2, varscan2
- ARHGAP20 | c.3067T>C p.W1023R | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99503645; called by muse, mutect2
- ARHGAP39 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs755955179, COSV52776232; called by muse, mutect2, varscan2
- ARHGAP44 | c.1988C>A p.P663Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV99310469; called by muse, mutect2, varscan2
- ARHGEF16 | c.893_895del p.S298del | In Frame Del (DEL) | VAF 27/66 reads (41%) | catalogued as rs765928654; called by mutect2, pindel, varscan2
- ARHGEF19 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs774766550, COSV99580287; called by muse, mutect2, varscan2
- ARHGEF2 | c.1234C>T p.R412C (on ENST00000361247 / NM_001162383.2; = p.R384C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.436); catalogued as rs781587819, COSV100560341; called by muse, mutect2, varscan2
- ARHGEF3 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1330576991, COSV99575163; called by muse, mutect2, varscan2
- ARHGEF40 | c.4144C>T p.R1382* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as rs758030337, COSV100070224; called by muse, varscan2
- ARHGEF5 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99282713; called by muse, mutect2, varscan2
- ARID1A | c.1655C>A p.S552* | Nonsense Mutation (SNP) | VAF 74/220 reads (34%) | catalogued as COSV100251083, COSV61372151, COSV61388437; called by muse, mutect2, varscan2
- ARID1B | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs762908553, COSV99268422; called by muse, mutect2, varscan2
- ARID2 | c.4391G>A p.R1464H | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); catalogued as rs770601353, COSV57603414; called by muse, mutect2, varscan2
- ARID3C | c.272del p.P91Lfs*44 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as rs1311009649; called by mutect2, pindel, varscan2
- ARID5A | c.1667del p.P556Qfs*145 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as rs1388296178; called by mutect2, pindel, varscan2
- ARMC6 | c.940G>A p.V314I (on ENST00000392336; = p.V289I on NM_033415.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs200795233, COSV54182861; called by muse, mutect2, varscan2
- ARMC9 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV100589639; called by muse, mutect2, varscan2
- ARNT | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.05); catalogued as rs765314219, COSV100591061; called by muse, mutect2, varscan2
- ARNT | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1312509595, COSV100591062; called by muse, mutect2, varscan2
- ARPP21 | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99491613; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs753865255; called by mutect2, varscan2
- ARVCF | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as COSV99258530; called by muse, mutect2, varscan2
- ASB4 | c.979-1G>T p.X327_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100367147; called by muse, mutect2, varscan2
- ASCC1 | c.687G>C p.Q229H (on ENST00000342444 / NM_001369085.1; = p.Q201H on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100403271; called by muse, mutect2, varscan2
- ASCC2 | c.2264T>A p.I755N | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100316175; called by muse, mutect2, varscan2
- ASH1L | c.8335G>A p.D2779N (on ENST00000368346 / NM_001366177.2; = p.D2774N on NM_018489.3) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100853313; called by muse, mutect2
- ASMTL | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1158958372, COSV101187732, COSV67242736; called by muse, mutect2, varscan2
- ASPA | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs2228435; called by muse, mutect2, varscan2
- ASPRV1 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100208460; called by muse, mutect2, varscan2
- ASTE1 | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV53907787; called by muse, mutect2, varscan2
- ASXL1 | c.3915del p.F1305Lfs*145 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as COSV60107158; called by mutect2, pindel, varscan2
- ATF7IP2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.214); catalogued as COSV100202570; called by muse, mutect2, varscan2
- ATG101 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs1324289088, COSV100400998; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs771531141; called by mutect2, varscan2
- ATM | c.3120G>A p.M1040I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV53771415, COSV99588980; called by muse, mutect2, varscan2
- ATP10A | c.3875T>C p.F1292S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100791074; called by muse, mutect2
- ATP11B | c.319T>C p.Y107H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100017681; called by muse, mutect2, varscan2
- ATP12A | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99517341; called by muse, mutect2, varscan2
- ATP12A | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.773); catalogued as COSV99517346; called by muse, mutect2, varscan2
- ATP13A2 | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.277); catalogued as rs764988645, COSV58700082; called by muse, mutect2, varscan2
- ATP13A2 | c.1354-2A>G p.X452_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100454037; called by muse, mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP2A2 | c.1613C>A p.S538Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100428518; called by muse, mutect2, varscan2
- ATP2B1 | c.2536C>T p.R846* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV53805755, COSV53811872; called by muse, mutect2, varscan2
- ATP2B2 | c.2336G>A p.R779H (on ENST00000352432; = p.R745H on NM_001683.5) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280783124, COSV100659922, COSV59497574; called by muse, mutect2, varscan2
- ATP4A | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1354006829, COSV52868783; called by muse, mutect2, varscan2
- ATP5F1C | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100184299; called by muse, mutect2, varscan2
- ATP7A | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374162669, COSV100430584; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- ATP7B | c.3680C>T p.A1227V | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99666278; called by muse, mutect2, varscan2
- ATRNL1 | c.576del p.F192Lfs*8 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs1554873914; called by mutect2, pindel, varscan2
- ATXN7 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.955); catalogued as rs771833920, COSV55752509; called by muse, mutect2, varscan2
- AVPR1A | c.1030A>G p.N344D | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100146817; called by muse, mutect2, varscan2
- AVPR1B | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs554894167, COSV65638224; called by muse, mutect2, varscan2
- AXIN1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759464398, COSV99249418, COSV99250343; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 37/103 reads (36%) | catalogued as rs778012871; called by mutect2, pindel, varscan2
- B3GLCT | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1358436411, COSV58454867; called by muse, mutect2, varscan2
- B3GLCT | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758647803, COSV58453711; called by muse, mutect2, varscan2
- B3GNT8 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1226227341, COSV99524517; called by muse, mutect2, varscan2
- B4GALNT1 | c.1511A>G p.Y504C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs759652761, COSV100247039; called by muse, mutect2, varscan2
- B4GALNT1 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100247040; called by muse, mutect2, varscan2
- B4GAT1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs376475080; called by muse, mutect2, varscan2
- BAP1 | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.751); catalogued as rs1553645130, COSV99963750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARD1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs730881416, COSV53619390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBX | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151079480; called by muse, mutect2, varscan2
- BCHE | c.1027del p.T343Pfs*16 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as CM025285, COSV52257903; called by mutect2, pindel, varscan2
- BCL2L2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.071); catalogued as rs746534702, COSV51635702; called by muse, mutect2, varscan2
- BCL9L | c.3380dup p.P1128Tfs*42 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | catalogued as rs751794665; called by mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 27/54 reads (50%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND3 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs147270081; called by muse, mutect2, varscan2
- BHLHE23 | c.319G>A p.A107T (on ENST00000370346; = p.A123T on NM_080606.4) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100947598; called by muse, mutect2, varscan2
- BICRA | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs756323742, COSV101194273; called by muse, mutect2, varscan2
- BICRAL | c.2552G>A p.S851N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV100017988; called by muse, mutect2, varscan2
- BIRC3 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs768158423, COSV54819569; called by muse, mutect2, varscan2
- BMP2K | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99785009; called by muse, mutect2, varscan2
- BMPR1A | c.230+2T>C p.X77_splice | Splice Site (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100776688, COSV63135361; called by muse, mutect2, varscan2
- BMPR1A | c.1126T>C p.C376R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100923432; called by muse, mutect2, varscan2
- BNC1 | c.983T>C p.I328T | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100597075; called by muse, mutect2, varscan2
- BORA | c.585A>C p.K195N (on ENST00000613797; = p.K120N on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100909667; called by muse, mutect2, varscan2
- BPIFA2 | c.398T>A p.V133D | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1187036823, COSV99487828; called by muse, mutect2
- BRAT1 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs759036645, COSV100500421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA1 | c.4098T>C p.G1366= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100523810; called by muse, mutect2
- BRCA2 | c.4178C>T p.A1393V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs398122776, COSV66448197; ClinVar: conflicting interpretations of pathogenicity / benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs763134487; called by mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BRWD1 | c.5446dup p.T1816Nfs*6 | Frame Shift Ins (INS) | VAF 34/94 reads (36%) | catalogued as rs1568856013; called by mutect2, varscan2
- BRWD3 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs372559820, COSV100955902; called by muse, mutect2, varscan2
- BSCL2 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99628115; called by mutect2, varscan2
- BSN | c.3202C>T p.R1068C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99607953; called by muse, mutect2, varscan2
- BTK | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100437513, COSV58117788; called by muse, mutect2, varscan2
- BTN2A2 | c.460del p.L154Sfs*40 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as COSV61856737; called by mutect2, pindel, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- BZW2 | c.638A>G p.D213G | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99334506; called by muse, mutect2, varscan2
- C12orf42 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV59385299; called by muse, mutect2, varscan2
- C12orf45 | c.551del p.K184Rfs*13 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs777032057; called by mutect2, varscan2
- C12orf50 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs758153766, COSV53895360; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 46/124 reads (37%) | catalogued as rs1558068270; called by mutect2, pindel, varscan2
- C20orf96 | c.337C>T p.R113* (on ENST00000360321 / NM_153269.3; = p.R112* on NM_080571.1) | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as rs769778652, COSV64402994; called by muse, mutect2, varscan2
- C2CD3 | c.5362A>G p.I1788V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100486441; called by muse, mutect2, varscan2
- C2orf42 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs781199379, COSV100033811; called by muse, mutect2, varscan2
- C3 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55577116; called by muse, mutect2, varscan2
- C7 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757348574, COSV100495553, COSV57477481, COSV57482578; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- CABLES2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs776946463, COSV54159079; called by muse, mutect2, varscan2
- CABS1 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV99909023; called by muse, mutect2, varscan2
- CACHD1 | c.568A>G p.S190G | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV99261953; called by muse, mutect2, varscan2
- CACHD1 | c.3704dup p.Q1236Sfs*23 | Frame Shift Ins (INS) | VAF 24/96 reads (25%) | catalogued as rs764948820; called by mutect2, varscan2
- CACNA1B | c.4337C>T p.A1446V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs755030668, COSV99496522; called by muse, mutect2, varscan2
- CACNA1D | c.818A>C p.H273P | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99857515; called by muse, mutect2, varscan2
- CACNA1E | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62416471; called by muse, mutect2, varscan2
- CACNA1I | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745960699, COSV100359852, COSV60800667; called by muse, mutect2, varscan2
- CACNA1S | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100754875; called by muse, mutect2, varscan2
- CACNA2D1 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100666340, COSV100666398; called by muse, varscan2
- CACTIN | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698407; called by muse, mutect2
- CAD | c.6074A>G p.H2025R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99254820; called by muse, mutect2, varscan2
- CADM1 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100522459; called by muse, mutect2, varscan2
- CALCOCO1 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100017252; called by muse, mutect2, varscan2
- CALD1 | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100724140; called by muse, mutect2, varscan2
- CALHM1 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99588435; called by muse, mutect2, varscan2
- CAMSAP2 | c.3789del p.K1263Nfs*19 (on ENST00000236925 / NM_001297707.2; = p.K1252Nfs*19 on NM_203459.3) | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | catalogued as rs770273913; called by mutect2, varscan2
- CAMTA2 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs776922330, COSV100772538; called by muse, mutect2, varscan2
- CAPN10 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99550136; called by muse, mutect2, varscan2
- CAPN2 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as rs773084596, COSV99688781; called by muse, varscan2
- CAPN2 | c.1487A>T p.D496V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99688789; called by muse, varscan2
- CARF | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778110847, COSV100247599; called by muse, mutect2, varscan2
- CASP10 | c.1501C>A p.L501M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as COSV99786947; called by muse, mutect2, varscan2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs931648756, COSV51845077; called by muse, mutect2, varscan2
- CAVIN2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.015); catalogued as rs374664652; called by muse, mutect2, varscan2
- CAVIN4 | c.739A>G p.R247G | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1336467530, COSV100293197; called by muse, mutect2, varscan2
- CBLB | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.127); catalogued as rs371406651, COSV51430268; called by muse, mutect2, varscan2
- CBLL2 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772801021, COSV100081544; called by muse, mutect2, varscan2
- CC2D1B | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1421130315, COSV99429892; called by muse, mutect2, varscan2
- CCDC113 | c.530A>T p.D177V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99540847; called by muse, mutect2, varscan2
- CCDC124 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs748636749, COSV71490600; called by muse, mutect2, varscan2
- CCDC142 | c.1705C>T p.P569S (on ENST00000393965 / NM_001365575.2; = p.P562S on NM_032779.4) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.776); catalogued as COSV99252070; called by muse, mutect2, varscan2
- CCDC144A | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV100502010; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 14/19 reads (74%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC7 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs554451471, COSV53235563; called by muse, mutect2, varscan2
- CCDC74A | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781396415, COSV54609605; called by muse, mutect2, varscan2
- CCDC83 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99721598; called by muse, mutect2, varscan2
- CCDC83 | c.1225A>G p.M409V (on ENST00000342404 / NM_001286159.2; = p.M440V on NM_173556.5) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99721600; called by muse, mutect2, varscan2
- CCNB3 | c.4114A>G p.I1372V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV99328816; called by muse, varscan2
- CCNL2 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs751164412, COSV68766331; called by muse, mutect2, varscan2
- CCT8L2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100743013; called by muse, mutect2
- CD163L1 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as COSV100549928; called by muse, mutect2, varscan2
- CD177 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as rs751529556, COSV100945909; called by muse, mutect2, varscan2
- CD177 | c.1258del p.V420Wfs*30 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as COSV65121341; called by mutect2, pindel, varscan2
- CD1E | c.642G>A p.W214* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs1453201541, COSV100936966; called by muse, mutect2, varscan2
- CDC20 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV100196405; called by muse, mutect2, varscan2
- CDC40 | c.818A>T p.K273M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100309229; called by muse, mutect2, varscan2
- CDC42BPA | c.3164T>C p.V1055A (on ENST00000334218 / NM_001366019.2; = p.V1042A on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs774212728, COSV100504478; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs762194001; called by mutect2, varscan2
- CDCP2 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562185443, COSV61286014; called by muse, mutect2, varscan2
- CDH10 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100050909; called by muse, mutect2, varscan2
- CDH23 | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.233); catalogued as rs1287154486, COSV99820165; called by muse, mutect2, varscan2
- CDH8 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.378); catalogued as rs771797284, COSV100180754; called by muse, mutect2, varscan2
- CDHR1 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as rs532268197, COSV100258705; called by muse, mutect2, varscan2
- CDHR3 | c.2210C>A p.A737D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as COSV100488183; called by muse, varscan2
- CDK14 | c.800C>T p.T267M (on ENST00000380050 / NM_001287135.2; = p.T249M on NM_012395.3) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.561); catalogued as rs376270298, COSV56049079; called by muse, mutect2, varscan2
- CDK17 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV99702616; called by muse, mutect2, varscan2
- CDK5RAP1 | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100212017; called by muse, mutect2, varscan2
- CDKL2 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100276834; called by muse, mutect2, varscan2
- CEACAM4 | c.581del p.P194Qfs*86 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs1555800891, COSV99701167; called by mutect2, pindel, varscan2
- CECR2 | c.2882C>T p.P961L (on ENST00000342247 / NM_001290047.2; = p.P778L on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs754756829, COSV52840539; called by muse, mutect2, varscan2
- CELSR1 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99417700; called by muse, mutect2, varscan2
- CELSR2 | c.5254G>A p.G1752S | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as rs1050401849, COSV54780983, COSV99604740; called by muse, mutect2, varscan2
- CEMIP | c.1391C>A p.P464H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV99586498; called by muse, mutect2, varscan2
- CENPP | c.601C>G p.P201A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99845532; called by muse, mutect2, varscan2
- CENPT | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs532792883, COSV99534978; called by muse, mutect2, varscan2
- CEP104 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764366578, COSV58215086; called by mutect2, varscan2
- CEP290 | c.6629G>A p.R2210H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as rs371833544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP350 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV62486180; called by mutect2, varscan2
- CEP85 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs772262341, COSV53329940; called by muse, mutect2, varscan2
- CEP95 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101616306; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP47 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.891); catalogued as COSV99934815; called by muse, mutect2, varscan2
- CFAP77 | c.633G>A p.R211= | Splice Region (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100545723; called by muse, mutect2, varscan2
- CFC1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs772626752, COSV99383460; called by muse, mutect2, varscan2
- CHAMP1 | c.2015A>G p.D672G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100778769; called by muse, mutect2, varscan2
- CHAT | c.1523A>C p.N508T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100339991; called by mutect2, varscan2
- CHD5 | c.5660del p.P1887Rfs*14 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs928253921; called by pindel, varscan2
- CHD5 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1333439739, COSV99313232; called by muse, mutect2, varscan2
- CHD6 | c.6575G>A p.R2192Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as rs200410567, COSV100950841; called by muse, mutect2, varscan2
- CHDH | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs767498767, COSV100179639; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHRD | c.1065+2T>C p.X355_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99200334; called by muse, mutect2, varscan2
- CHRNA4 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766414326, COSV64719000; called by muse, mutect2, varscan2
- CHRNA7 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181072; called by muse, varscan2
- CHST1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100346085, COSV100346163; called by muse, mutect2, varscan2
- CHST5 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781527035, COSV60336737; called by muse, mutect2, varscan2
- CIITA | c.1962del p.A656Pfs*30 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as COSV60863473; called by mutect2, pindel, varscan2
- CIITA | c.3376C>T p.R1126W | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60862083; called by muse, mutect2, varscan2
- CILP2 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV99364539; called by muse, mutect2, varscan2
- CILP2 | c.957del p.M320Cfs*74 | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | catalogued as rs759895052; called by mutect2, pindel, varscan2
- CKAP2L | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1452096705, COSV56698505; called by muse, mutect2, varscan2
- CLCN4 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV101073752; called by muse, mutect2, varscan2
- CLCN4 | c.1973T>C p.I658T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101073754; called by muse, mutect2, varscan2
- CLCN6 | c.805T>G p.S269A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV100411789; called by muse, mutect2, varscan2
- CLCN6 | c.975dup p.C326Mfs*46 | Frame Shift Ins (INS) | VAF 47/181 reads (26%) | catalogued as rs1446648587; called by mutect2, pindel, varscan2
- CLCN6 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100411791; called by muse, mutect2, varscan2
- CLEC2L | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.684); catalogued as COSV101406068; called by muse, mutect2, varscan2
- CLEC4C | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.301); catalogued as rs1193664214, COSV100665418; called by muse, mutect2, varscan2
- CLIP2 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99791319; called by muse, mutect2, varscan2
- CLK3 | c.805G>A p.A269T (on ENST00000395066 / NM_001130028.1; = p.A121T on NM_003992.4) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs148465298; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 66/96 reads (69%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSTN2 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs756137891, COSV101515641; called by muse, mutect2, varscan2
- CLTB | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766376751, COSV100124948; called by muse, mutect2, varscan2
- CLUH | c.2878G>C p.D960H (on ENST00000435359; = p.D999H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101425703; called by muse, mutect2, varscan2
- CNGA1 | c.1327del p.T443Qfs*8 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs772867912; called by mutect2, pindel, varscan2
- CNNM2 | c.414del p.A139Rfs*105 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as COSV63996447; called by mutect2, pindel
- CNOT3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751208319, COSV55366228; called by muse, mutect2, varscan2
- CNOT3 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1195831069, COSV99651672; called by muse, mutect2, varscan2
- CNOT6L | c.917C>T p.A306V (on ENST00000504123 / NM_001286790.2; = p.A301V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1481358623, COSV53698148; called by muse, mutect2, varscan2
- CNTN2 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs556646437, COSV100084861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN4 | c.1874G>T p.S625I | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100638864, COSV100639136; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs758676375; called by mutect2, varscan2
- COG3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776653139, COSV100596468; called by muse, mutect2, varscan2
- COG3 | c.2156T>G p.V719G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV100596469; called by muse, mutect2, varscan2
- COG8 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99650684; called by muse, mutect2, varscan2
- COL11A2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as rs780662619, COSV100553743; called by muse, mutect2, varscan2
- COL24A1 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100993135, COSV100993936; called by muse, mutect2, varscan2
- COL28A1 | c.855+2T>C p.X285_splice | Splice Site (SNP) | VAF 53/162 reads (33%) | catalogued as COSV101258475; called by muse, mutect2, varscan2
- COL2A1 | c.1255A>G p.K419E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100476085; called by muse, mutect2, varscan2
- COL4A4 | c.4679G>A p.R1560H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.591); catalogued as rs747362746, COSV61630559; called by muse, mutect2, varscan2
- COL6A2 | c.2843C>T p.T948M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367980010, COSV52426369; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.8008G>A p.A2670T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs398124135, COSV55112590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLEC11 | c.327A>G p.P109= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99363084; called by muse, varscan2
- COLEC12 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101232026; called by muse, mutect2, varscan2
- COMP | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs1416152202, COSV55874591; called by muse, mutect2, varscan2
- COPB1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777777654, COSV99999443; called by muse, mutect2, varscan2
- COPB1 | c.456A>C p.R152S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99999445; called by muse, mutect2, varscan2
- COPB1 | c.83del p.N28Mfs*3 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs1258568005; called by mutect2, pindel, varscan2
- COPB2 | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.264); catalogued as COSV100169030; called by muse, mutect2, varscan2
- COPG1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1448297813, COSV59115075; called by muse, mutect2
- COQ8A | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777934964, COSV64657056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CP | c.1227dup p.E410* | Frame Shift Ins (INS) | VAF 31/100 reads (31%) | catalogued as rs1442529216; called by mutect2, pindel, varscan2
- CPEB4 | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV99436942; called by muse, mutect2, varscan2
- CPS1 | c.4112G>A p.R1371Q | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs765106604, CM114387, COSV51802810, COSV51802996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 65/272 reads (24%) | catalogued as rs772054700, COSV58879005; called by mutect2, pindel, varscan2
- CREB1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV100783562; called by muse, mutect2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 41/116 reads (35%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRIM1 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs746293769, COSV54862692; called by muse, mutect2, varscan2
- CRISP3 | c.478C>T p.P160S (on ENST00000371159 / NM_001368123.1; = p.P142S on NM_006061.4) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV99538843; called by muse, mutect2, varscan2
- CRX | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs142111462, COSV55759068; called by muse, mutect2, varscan2
- CRY1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs753452380, COSV50484161; called by muse, mutect2, varscan2
- CRYAB | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM120280, COSV99909805; called by muse, mutect2, varscan2
- CSAD | c.1139G>A p.R380H (on ENST00000444623 / NM_001244705.2; = p.R407H on NM_015989.5) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.713); catalogued as rs746587061, COSV57241642; called by muse, mutect2, varscan2
- CSF3R | c.2117C>A p.P706Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.124); catalogued as COSV100117521, COSV58964271; called by muse, mutect2, varscan2
- CSMD3 | c.8122C>T p.R2708* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs773340701, COSV52214384; called by muse, mutect2, varscan2
- CSMD3 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 31/105 reads (30%) | catalogued as rs779460744, COSV52105745, COSV99830721; called by muse, mutect2, varscan2
- CTCF | c.1451A>C p.Q484P | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99864943; called by muse, mutect2, varscan2
- CTDP1 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs760761980, COSV99310383; called by muse, mutect2, varscan2
- CTLA4 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs376038796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTLA4 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99865211; called by muse, mutect2, varscan2
- CTNNA1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs746832628, COSV57072983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA1 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as COSV100242496; called by muse, mutect2, varscan2
- CTNNA2 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1417541064, COSV100783948, COSV63554502; called by muse, mutect2, varscan2
- CTNND2 | c.1006A>C p.T336P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.255); catalogued as COSV100474786; called by muse, mutect2, varscan2
- CTNS | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV50440292, COSV99251159; called by muse, mutect2, varscan2
- CUBN | c.4771G>A p.V1591I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs201056237; called by muse, mutect2, varscan2
- CUX1 | c.1130C>T p.A377V (on ENST00000292535 / NM_181552.4; = p.A388V on NM_001913.5) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV99471098; called by muse, mutect2, varscan2
- CUX1 | c.1664A>G p.Y555C (on ENST00000437600 / NM_181500.4; = p.Y557C on NM_001913.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV52929073; called by muse, mutect2, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 77/258 reads (30%) | catalogued as rs775988957; called by mutect2, pindel, varscan2
- CYBB | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.988); catalogued as COSV101059730; called by muse, mutect2, varscan2
- CYFIP1 | c.3658A>C p.T1220P | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs771581093, COSV100488068; called by muse, mutect2, varscan2
- CYP20A1 | c.679+1G>A p.X227_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100619029, COSV61910346; called by muse, mutect2
- CYP51A1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.5); catalogued as COSV99133717; called by muse, mutect2, varscan2
- CYSLTR1 | c.671del p.N224Ifs*9 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as rs766746913; called by mutect2, varscan2
- CYTH4 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as rs138097924; called by muse, mutect2, varscan2
- DAPK1 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV100801544; called by muse, mutect2
- DAPK1 | c.2737G>C p.E913Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.979); catalogued as COSV100801546; called by muse, mutect2, varscan2
- DAPL1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100007301, COSV59356618; called by muse, mutect2, varscan2
- DCAF10 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99647633; called by muse, mutect2, varscan2
- DCAF12L2 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs762618000, COSV63583335; called by muse, mutect2, varscan2
- DCAF4L1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369697482; called by muse, mutect2, varscan2
- DCAF8 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1205424160, COSV100470166; called by muse, mutect2, varscan2
- DCTN1 | c.1537T>C p.Y513H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100720905; called by muse, mutect2, varscan2
- DDOST | c.908_910del p.E303del (on ENST00000415136; = p.E286del on NM_005216.5) | In Frame Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs1557571295; called by pindel, varscan2
- DDRGK1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs944437684, COSV100621404; called by muse, mutect2, varscan2
- DDX27 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.416); catalogued as rs1169246657, COSV100873323; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX39B | c.447dup p.G150Wfs*9 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | catalogued as rs777891843; called by mutect2, varscan2
- DDX43 | c.865G>T p.G289* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100946298; called by muse, mutect2, varscan2
- DDX60 | c.4849A>G p.N1617D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV101190387; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as rs772416332; called by mutect2, varscan2
- DEGS2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99979172; called by muse, mutect2, varscan2
- DENND1C | c.1897A>T p.S633C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100375258; called by muse, mutect2, varscan2
- DENND4A | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324199204, COSV71265135; called by muse, mutect2, varscan2
- DEPDC5 | c.2384C>T p.T795M (on ENST00000400246; = p.T864M on NM_014662.5) | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99834997; called by muse, mutect2, varscan2
- DEPDC7 | c.628C>T p.R210C (on ENST00000241051 / NM_001077242.2; = p.R201C on NM_139160.2) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749658035, COSV53806174, COSV53807601; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DHX34 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553380305, COSV60898753; called by muse, mutect2, varscan2
- DHX57 | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.581); catalogued as rs772949216, COSV54887311, COSV99769326; called by muse, mutect2, varscan2
- DHX57 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV99769330; called by muse, mutect2, varscan2
- DLG2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54631130, COSV99714552; called by muse, mutect2, varscan2
- DLG4 | c.1639G>A p.A547T (on ENST00000399506 / NM_001321075.3; = p.A590T on NM_001365.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs760656143, COSV57237244; called by muse, mutect2, varscan2
- DLG5 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758483656, COSV64948847; called by muse, mutect2, varscan2
- DLGAP1 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1258270976, COSV59814670; called by muse, mutect2, varscan2
- DLST | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs141349679; called by muse, varscan2
- DMAP1 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); catalogued as rs948379587, COSV60001641; called by muse, mutect2, varscan2
- DMTF1 | c.877A>G p.S293G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100487344; called by muse, mutect2, varscan2
- DMTN | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99741630; called by muse, mutect2, varscan2
- DMXL2 | c.1001T>C p.L334S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.125); catalogued as COSV99196188; called by muse, mutect2, varscan2
- DMXL2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753290975, COSV51844140; called by muse, mutect2, varscan2
- DNAH1 | c.7075C>T p.R2359C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774675368, COSV101325400; called by muse, mutect2, varscan2
- DNAH1 | c.9781C>T p.R3261C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs150835931, COSV101325402; called by mutect2, varscan2
- DNAH11 | c.5923A>T p.R1975* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100178523; called by muse, mutect2, varscan2
- DNAH17 | c.10817C>T p.A3606V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs560286800, COSV67753129; called by muse, mutect2, varscan2
- DNAH5 | c.12814T>C p.F4272L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV99447933; called by muse, mutect2, varscan2
- DNAH9 | c.13141A>G p.T4381A | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99305196; called by muse, mutect2, varscan2
- DNAI3 | c.659A>C p.N220T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54005599; called by muse, mutect2, varscan2
- DNAJB7 | c.884del p.K295Rfs*25 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | catalogued as rs768619916; called by mutect2, varscan2
- DNAJC13 | c.4998del p.G1667Vfs*22 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | catalogued as COSV53444955; called by mutect2, pindel, varscan2
- DNAJC14 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as rs769086235, COSV100423555; called by muse, mutect2, varscan2
- DNAJC16 | c.2324T>G p.I775S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV101011768; called by muse, mutect2
- DNAJC22 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV101222507; called by muse, mutect2
- DNM2 | c.1324T>C p.C442R | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100117070; called by muse, mutect2, varscan2
- DNMT3A | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs375399431, COSV53043522; called by muse, mutect2, varscan2
- DNMT3A | c.176del p.P59Rfs*13 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV53040261; called by mutect2, pindel, varscan2
- DNMT3L | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.086); catalogued as COSV99533215; called by muse, mutect2, varscan2
- DOCK1 | c.3522_3524del p.V1175del | In Frame Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs1565037300; called by mutect2, varscan2
- DOCK3 | c.5366G>A p.R1789H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs777938666, COSV99810765; called by muse, mutect2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs748134881; called by mutect2, varscan2
- DOK4 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99538273; called by muse, mutect2, varscan2
- DOP1B | c.663del p.T222Pfs*7 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as COSV67695054; called by pindel, varscan2
- DOP1B | c.4591G>A p.G1531R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767936629, COSV101215223; called by muse, mutect2, varscan2
- DPEP1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs762596549, COSV99878428; called by muse, mutect2, varscan2
- DPP8 | c.561T>A p.Y187* (on ENST00000341861 / NM_001320875.2; = p.Y171* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 50/106 reads (47%) | catalogued as COSV100202236; called by muse, mutect2, varscan2
- DPP9 | c.2348C>T p.A783V (on ENST00000598800; = p.A812V on NM_139159.5) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.225); catalogued as rs373425668, COSV53595839; called by muse, mutect2, varscan2
- DPP9 | c.1858C>T p.R620W (on ENST00000598800; = p.R649W on NM_139159.5) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs187881686, COSV99505919; called by muse, mutect2, varscan2
- DSCAML1 | c.952C>T p.R318C (on ENST00000321322; = p.R258C on NM_020693.4) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58384642; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs750962255; called by mutect2, varscan2
- DSTYK | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752673167, COSV100904515; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DUSP10 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245367877, COSV60457241; called by muse, mutect2, varscan2
- DYNC1I2 | c.1008G>A p.M336I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV99783768; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs751377941; called by mutect2, varscan2
- DYNLL1 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.13); catalogued as rs796315584, COSV99655549; called by muse, mutect2, varscan2
- DYRK2 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV100165250; called by muse, mutect2
- DYRK2 | c.1447C>T p.R483W (on ENST00000344096 / NM_006482.3; = p.R410W on NM_003583.4) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748801595, COSV100165252; called by muse, mutect2, varscan2
- DYSF | c.3059dup p.E1021Gfs*11 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | catalogued as rs753711667; called by mutect2, pindel, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | catalogued as rs752987091; called by mutect2, varscan2
- EDNRB | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57520081; called by muse, mutect2, varscan2
- EEF2 | c.2414G>A p.G805D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100500669; called by muse, mutect2, varscan2
- EFCAB5 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs369999418, COSV57938044; called by muse, mutect2, varscan2
- EFTUD2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765588398, COSV68183025; called by muse, mutect2, varscan2
- EGFR | c.3453C>A p.F1151L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51766010, COSV99289543; called by muse, mutect2, varscan2
- EGR2 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV54347323, COSV99654061; called by muse, mutect2, varscan2
- EGR4 | c.1514G>A p.R505H (on ENST00000545030; = p.R402H on NM_001965.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101474231; called by muse, mutect2, varscan2
- EGR4 | c.1231C>T p.Q411* (on ENST00000545030; = p.Q308* on NM_001965.4) | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV101474232; called by muse, mutect2
- EHD2 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs775528505, COSV99621841; called by muse, mutect2, varscan2
- EHMT1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768764806, COSV58380724; called by muse, mutect2, varscan2
- EHMT1 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101509623; called by muse, mutect2, varscan2
- EHMT1 | c.3398C>T p.T1133M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754986694, COSV101509624; called by muse, mutect2, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF2AK3 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as CD097431, COSV100303626; called by muse, mutect2, varscan2
- EIF3B | c.1931C>T p.T644M | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs181409131, COSV100703502; called by muse, mutect2, varscan2
- EIF3L | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs201577615, COSV65951851; called by muse, mutect2, varscan2
- ELAVL1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.58); catalogued as COSV100688298, COSV100688434; called by muse, mutect2, varscan2
- ELOVL2 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753752578, COSV100675840; called by muse, mutect2, varscan2
- ELOVL6 | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100165096; called by muse, mutect2, varscan2
- EMC2 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); catalogued as COSV99624033; called by muse, mutect2, varscan2
- EMILIN2 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as rs749622305, COSV54422508, COSV54425099; called by muse, mutect2, varscan2
- EMILIN3 | c.2259G>T p.Q753H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV100182489; called by muse, mutect2, varscan2
- EMILIN3 | c.1099T>C p.S367P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100182491; called by muse, mutect2, varscan2
- EML1 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs772174519, COSV51746088; called by muse, mutect2
- EML3 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV99605849; called by muse, mutect2, varscan2
- ENTPD7 | c.1137G>T p.W379C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100978383; called by muse, mutect2, varscan2
- ENTR1 | c.1159G>A p.A387T (on ENST00000357365 / NM_001039707.2; = p.A364T on NM_006643.4) | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100048095; called by muse, mutect2, varscan2
- EP300 | c.4190A>G p.Y1397C | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54329112, COSV54347367, COSV99608130; called by muse, varscan2
- EPAS1 | c.1781G>T p.S594I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as COSV99763086; called by muse, mutect2, varscan2
- EPB41L1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs993735906, COSV52435435; called by muse, mutect2, varscan2
- EPHA4 | c.1443+2T>C p.X481_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV56031640, COSV99916186; called by muse, mutect2, varscan2
- EPHA5 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746706656, COSV56639139; called by muse, mutect2, varscan2
- EPHA6 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs774575382, COSV101061747; called by muse, mutect2, varscan2
- EPHA7 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV100993533; called by muse, mutect2, varscan2
- EPHB2 | c.1907G>A p.C636Y (on ENST00000400191 / NM_001309193.2; = p.C637Y on NM_004442.7) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV101006885; called by muse, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 29/80 reads (36%) | catalogued as rs756461692; called by mutect2, varscan2
- EPN3 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1362425771, COSV52139814; called by muse, mutect2, varscan2
- EPS8L1 | c.1086del p.P363Rfs*12 (on ENST00000201647 / NM_133180.3; = p.P236Rfs*12 on NM_017729.3) | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs746955003, COSV99136727; called by mutect2, pindel, varscan2
- ERBB2 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs766029214, COSV99507471; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs753821453; called by mutect2, varscan2
- ESR1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.213); catalogued as rs771540162, COSV52790749; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | catalogued as rs775950025; called by mutect2, varscan2
- ETAA1 | c.369del p.K123Nfs*46 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs1298232483; called by mutect2, pindel, varscan2
- ETV5 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100112058; called by muse, mutect2, varscan2
- EVA1A | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV99285458; called by muse, mutect2, varscan2
- EVA1C | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100291281; called by muse, mutect2, varscan2
- EVC2 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs780323237, COSV100185629; called by muse, mutect2, varscan2
- EVI5L | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs867547729, COSV99075330; called by muse, mutect2, varscan2
- EVPL | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs777686326, COSV56910219; called by muse, mutect2, varscan2
- EXOC4 | c.2252del p.P751Qfs*32 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs1563085372; called by mutect2, pindel, varscan2
- EXPH5 | c.5422C>T p.R1808* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs142805294; called by muse, mutect2, varscan2
- EXT1 | c.1687A>G p.S563G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100983858; called by muse, mutect2, varscan2
- EYA3 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.585); catalogued as rs1274692706, COSV100870236; called by muse, mutect2, varscan2
- F7 | c.720del p.T241Pfs*2 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | catalogued as CM010249; called by mutect2, pindel, varscan2
- FAM102A | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.136); catalogued as COSV100305473; called by muse, mutect2, varscan2
- FAM131B | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 33/137 reads (24%) | catalogued as COSV100577929; called by muse, mutect2, varscan2
- FAM13A | c.2359A>G p.S787G | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV99983303; called by muse, mutect2
- FAM172A | c.786+2T>C p.X262_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | catalogued as COSV101232711; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM214A | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as rs969658360, COSV55927469; called by muse, mutect2, varscan2
- FAM222A | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV100734510; called by muse, mutect2, varscan2
- FAM47B | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs377583305, COSV100264235; called by muse, mutect2, varscan2
- FAM47C | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.509); catalogued as rs1427563293, COSV100792436; called by muse, mutect2, varscan2
- FAM53A | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252047894, COSV100356938; called by muse, mutect2, varscan2
- FAM53A | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370251492; called by muse, varscan2
- FAM53C | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs764891439, COSV99524304; called by muse, mutect2, varscan2
- FAM83B | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs768677387, COSV60923191; called by muse, mutect2, varscan2
- FAM83G | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1197063594, COSV100524689; called by muse, varscan2
- FAM83G | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1166072864, COSV58762574; called by muse, mutect2, varscan2
- FAM98C | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442170374, COSV53038873, COSV53039384; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs748967872; called by mutect2, varscan2
- FANCA | c.2655G>T p.E885D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59798233; called by muse, mutect2, varscan2
- FANCC | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100002332; called by muse, mutect2, varscan2
- FARSA | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241498868, COSV100108762; called by muse, mutect2, varscan2
- FAT2 | c.9851G>A p.S3284N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99942355; called by muse, mutect2, varscan2
- FAT2 | c.131A>C p.E44A | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99942359; called by muse, mutect2, varscan2
- FAT4 | c.6361A>G p.T2121A | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV100628105; called by muse, mutect2, varscan2
- FBH1 | c.2285C>T p.T762M (on ENST00000362091 / NM_178150.3; = p.T813M on NM_032807.4) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100758686; called by muse, mutect2, varscan2
- FBLN1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs141938890; called by muse, mutect2, varscan2
- FBLN2 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs1370281595, COSV55482438; called by muse, mutect2, varscan2
- FBLN2 | c.3421G>A p.V1141M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as COSV99851666; called by muse, mutect2, varscan2
- FBN1 | c.2212A>T p.I738F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.377); catalogued as COSV100354528; called by muse, mutect2, varscan2
- FBXL17 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs368164862; called by muse, mutect2, varscan2
- FBXL7 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.103); catalogued as rs548322966, COSV61642962, COSV61648367; called by muse, mutect2, varscan2
- FBXO31 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61149192; called by muse, mutect2, varscan2
- FBXW11 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs776500801, COSV51614923, COSV99440184; called by muse, mutect2, varscan2
- FBXW7 | c.2021G>A p.R674Q (on ENST00000281708 / NM_001349798.2; = p.R594Q on NM_018315.5) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.972); catalogued as COSV55894253; called by muse, mutect2, varscan2
- FCHO1 | c.2180A>G p.Q727R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV99406008; called by muse, mutect2, varscan2
- FCHSD1 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs866116457, COSV99781283; called by muse, mutect2, varscan2
- FCN1 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878870; called by muse, mutect2, varscan2
- FES | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1170471078, COSV100182979; called by muse, mutect2, varscan2
- FGD6 | c.3895T>C p.S1299P | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100676494; called by muse, mutect2, varscan2
- FGF11 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV99548215; called by muse, mutect2, varscan2
- FGF14 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101085562; called by muse, mutect2, varscan2
- FGF3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782147248, COSV61925745; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | catalogued as rs144178676; called by mutect2, varscan2
- FGFR2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as rs1441011501, COSV60646187; called by muse, mutect2, varscan2
- FGFRL1 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461069330, COSV99294580; called by muse, mutect2, varscan2
- FHOD1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99264003; called by muse, mutect2, varscan2
- FICD | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as COSV99933999; called by muse, mutect2
- FIGNL2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs781164340; called by muse, mutect2, varscan2
- FIS1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.944); catalogued as COSV99778922; called by muse, mutect2, varscan2
- FLG2 | c.3380G>A p.G1127D | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1557897561, COSV101165773; called by muse, mutect2, varscan2
- FLI1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs754322278, COSV61378190; called by muse, mutect2
- FMN2 | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.174); catalogued as rs142072223, COSV60444287; called by muse, varscan2
- FMNL3 | c.1903A>G p.K635E | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99525937; called by muse, mutect2, varscan2
- FNDC1 | c.2867C>T p.T956I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV99795441; called by muse, mutect2, varscan2
- FNDC11 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as rs776604532, COSV64443127; called by muse, mutect2, varscan2
- FNDC8 | c.467T>G p.L156R | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99338726; called by muse, mutect2, varscan2
- FOXB1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.959); catalogued as COSV101249628; called by muse, mutect2
- FOXD4L4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1352810874; called by muse, varscan2
- FOXK2 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100081961; called by muse, mutect2, varscan2
- FOXP1 | c.1166T>C p.V389A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100561391; called by muse, mutect2, varscan2
- FOXRED1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1378537986, COSV99702714; called by muse, mutect2
- FOXRED2 | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV99340811; called by muse, mutect2, varscan2
- FRAS1 | c.8510C>T p.A2837V | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99350393; called by muse, mutect2, varscan2
- FREM2 | c.8984T>C p.V2995A | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV99748123; called by muse, mutect2
- FSCN1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs754279900, COSV100435089; called by muse, mutect2, varscan2
- FSTL4 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV99532108; called by muse, mutect2, varscan2
- FSTL4 | c.539A>T p.E180V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV99532109; called by muse, mutect2
- FTO | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs777196899, COSV101149956; called by muse, mutect2, varscan2
- FYB1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.134); catalogued as rs764819701, COSV100685218; called by muse, mutect2, varscan2
- FYCO1 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV99945133; called by muse, mutect2, varscan2
- FZD1 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99842475; called by muse, mutect2, varscan2
- FZD8 | c.1247T>A p.I416N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101020209; called by muse, mutect2, varscan2
- GABRG2 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs1194428749, COSV100729639; called by muse, mutect2, varscan2
- GALNT11 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533548373, COSV57428554; called by muse, mutect2, varscan2
- GALNT11 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as rs766807653, COSV57424702; called by muse, mutect2, varscan2
- GALR2 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100135086; called by muse, mutect2, varscan2
- GAPVD1 | c.674G>T p.R225M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99782980; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | catalogued as rs758551787; called by mutect2, varscan2
- GAS2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1372094047, COSV53410207; called by muse, mutect2, varscan2
- GBP4 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs200823724, COSV100864336; called by muse, mutect2, varscan2
- GCSAM | c.151dup p.I51Nfs*5 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs762814436; called by mutect2, varscan2
- GDA | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs932604407, COSV52993612; called by muse, mutect2, varscan2
- GEMIN4 | c.1288_1290del p.K430del | In Frame Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs761928133; called by pindel, varscan2
- GET4 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as rs369193824; called by muse, mutect2, varscan2
- GFOD1 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs767747080, COSV64954491; called by muse, mutect2, varscan2
- GGN | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs765574791, COSV53056171; called by muse, mutect2, varscan2
- GHDC | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.389); catalogued as COSV100054599; called by muse, mutect2, varscan2
- GIGYF2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1309356302, COSV65246443; called by muse, mutect2, varscan2
- GIT1 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs376860718; called by muse, mutect2, varscan2
- GJA8 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99569259; called by muse, mutect2, varscan2
- GJA9 | c.47T>C p.I16T | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV100668068; called by muse, mutect2
- GJC2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100812907; called by muse, mutect2, varscan2
- GKN2 | c.455A>T p.E152V | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100187759; called by muse, mutect2, varscan2
- GKN2 | c.140del p.N47Ifs*38 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as COSV61032094; called by mutect2, pindel, varscan2
- GLB1L2 | c.1050A>T p.E350D | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100335261; called by muse, mutect2
- GLIPR1L2 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100248519; called by muse, varscan2
- GLT8D2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as rs766554936, COSV62561857; called by muse, mutect2, varscan2
- GLUD2 | c.4T>C p.Y2H | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs776326320, COSV100046714; called by muse, mutect2, varscan2
- GNA15 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs764000592, COSV53587793; called by muse, mutect2, varscan2
- GNAO1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.485); catalogued as rs1380348729, COSV99341001; called by muse, mutect2
- GNB5 | c.736G>C p.A246P (on ENST00000261837 / NM_016194.4; = p.A204P on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.65); catalogued as COSV99953234; called by muse, mutect2, varscan2
- GNRH1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1336171284, CM162730, COSV99373591; called by muse, mutect2, varscan2
- GOLGA2 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV101425853; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | catalogued as rs370114090; called by mutect2, varscan2
- GPATCH4 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100576905; called by muse, mutect2, varscan2
- GPC1 | c.451T>C p.Y151H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99882767; called by muse, mutect2, varscan2
- GPHN | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs530173903, COSV59480870; called by muse, mutect2, varscan2
- GPR137B | c.117del p.Y40Tfs*2 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs768730454; called by mutect2, pindel, varscan2
- GPR151 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs762983992, COSV99694665; called by muse, mutect2, varscan2
- GPR156 | c.1925G>A p.S642N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100251277; called by muse, mutect2, varscan2
- GPR156 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs575756351, COSV59943160; called by muse, mutect2, varscan2
- GPR158 | c.2635T>C p.S879P | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100893207; called by muse, mutect2, varscan2
- GPR37L1 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV100938532; called by muse, varscan2
- GPR6 | c.788A>C p.Q263P | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV99254238; called by muse, varscan2
- GPRC5B | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV100315030; called by muse, mutect2, varscan2
- GPSM2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV99915161; called by muse, mutect2, varscan2
- GRAMD1C | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100822848; called by muse, mutect2, varscan2
- GREB1 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs755525854, COSV99302693; called by muse, mutect2, varscan2
- GREM2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs776488462, COSV100547432; called by muse, mutect2, varscan2
- GRIA1 | c.14T>G p.F5C | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV99599138; called by muse, mutect2
- GRID1 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.999); catalogued as rs770160415, COSV60012059, COSV60039732; called by muse, mutect2, varscan2
- GRIK1 | c.1352T>C p.V451A | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100413104; called by muse, mutect2, varscan2
- GRIK3 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV100901770; called by mutect2, varscan2
- GRIN2A | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs534440095, COSV58020882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM5 | c.2842G>A p.V948I (on ENST00000305447 / NM_001143831.2; = p.V916I on NM_000842.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs763053784, COSV59632919; called by muse, mutect2, varscan2
- GRM7 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as COSV63144426; called by muse, mutect2
- GRM7 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs767400612, COSV63134452; called by muse, mutect2, varscan2
- GRM7 | c.2576G>A p.R859Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs369197989; called by muse, varscan2
- GSE1 | c.2407A>G p.T803A | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99496365, COSV99496554; called by muse, mutect2
- GSK3A | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99725191; called by muse, mutect2, varscan2
- GSK3B | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99954492; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs763161381; called by mutect2, varscan2
- GTF3C1 | c.4949G>A p.G1650D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649228; called by muse, mutect2, varscan2
- GTF3C1 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100649232; called by muse, mutect2, varscan2
- GTF3C5 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565359; called by muse, mutect2
- GTPBP6 | c.872G>T p.R291M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100397700; called by muse, mutect2, varscan2
- GUCY1A1 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV99637540; called by muse, mutect2
- GUCY1B1 | c.1112T>C p.I371T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.245); catalogued as COSV100025474; called by muse, mutect2, varscan2
- GUCY2C | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV99663482; called by muse, mutect2
- GUF1 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.727); catalogued as rs954790549, COSV99877200; called by muse, mutect2, varscan2
- GYS2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs958670031, COSV53925338; called by muse, mutect2, varscan2
- GZF1 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347453704, COSV100582470; called by muse, mutect2, varscan2
- H1-1 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs888155690, COSV99771984; called by muse, mutect2, varscan2
- H2AC1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs375336327, COSV51238617; called by muse, mutect2, varscan2
- H2BC18 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV100516072; called by muse, mutect2, varscan2
- H4C1 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.786); catalogued as rs1313363695, COSV55120586; called by muse, mutect2, varscan2
- HACD1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs146922579; called by muse, mutect2, varscan2
- HADHA | c.1754C>G p.A585G | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV101023841; called by muse, mutect2
- HARS1 | c.1204_1206del p.E402del | In Frame Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs748455791; called by pindel, varscan2
- HARS2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.692); catalogued as COSV99218032; called by muse, mutect2
- HAS1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761590658, COSV55789522; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | catalogued as rs748396956; called by mutect2, varscan2
- HAUS5 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs370143349; called by muse, varscan2
- HCN1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100299660; called by muse, mutect2, varscan2
- HCN2 | c.2080A>C p.I694L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV99241554; called by muse, mutect2, varscan2
- HCN4 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs760413254, COSV99983529; called by muse, mutect2, varscan2
- HCRTR2 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100904278; called by muse, mutect2, varscan2
- HDAC4 | c.3215+1G>C p.X1072_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100613143; called by muse, mutect2, varscan2
- HDAC5 | c.2322G>T p.K774N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99870500; called by muse, mutect2, varscan2
- HDAC9 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs759293177, COSV67772925; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HECTD4 | c.13100del p.P4367Qfs*21 | Frame Shift Del (DEL) | VAF 37/111 reads (33%) | catalogued as rs746492036; called by mutect2, pindel, varscan2
- HERC1 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs371163845; called by muse, mutect2, varscan2
- HERC2 | c.4034G>A p.G1345D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99872499; called by mutect2, varscan2
- HGFAC | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.017); catalogued as rs748796749, COSV100122772; called by muse, mutect2, varscan2
- HIPK4 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs201085696, COSV52523374; called by muse, mutect2, varscan2
- HIVEP2 | c.7223C>T p.T2408M | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs375974004; called by muse, mutect2, varscan2
- HIVEP3 | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99912142; called by muse, mutect2, varscan2
- HK2 | c.1697T>C p.V566A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.503); catalogued as COSV99308853; called by muse, mutect2, varscan2
- HK3 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs780234736, COSV52837541; called by muse, mutect2, varscan2
- HLA-E | c.548A>C p.D183A | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100931896; called by muse, mutect2, varscan2
- HLX | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV100854507; called by muse, mutect2
- HMGXB4 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as rs762501665, COSV99330004; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 38/74 reads (51%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPA1L2 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100676473; called by muse, mutect2, varscan2
- HORMAD1 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100464001; called by muse, mutect2, varscan2
- HOXA9 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV100604374; called by muse, mutect2, varscan2
- HOXB3 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs745805494, COSV100290598; called by muse, mutect2, varscan2
- HOXD8 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100497055, COSV100497193; called by muse, mutect2, varscan2
- HPCAL1 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs375884714; called by muse, mutect2, varscan2
- HPS5 | c.424G>A p.D142N (on ENST00000349215 / NM_181507.2; = p.D28N on NM_007216.4) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834401; called by muse, mutect2, varscan2
- HRNR | c.3146G>A p.G1049D | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV100913120, COSV100913279; called by muse, mutect2, varscan2
- HRNR | c.604T>A p.S202T | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100913280; called by muse, mutect2, varscan2
- HS3ST1 | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99136750; called by muse, mutect2, varscan2
- HSCB | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV99319687; called by muse, mutect2, varscan2
- HSF2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100869669, COSV63773883; called by muse, varscan2
- HSF4 | c.1323A>G p.P441= (on ENST00000521374 / NM_001040667.3; = p.P411= on NM_001538.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99220469; called by muse, mutect2, varscan2
- HSPA12A | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as rs1051406561, COSV100979754; called by muse, mutect2, varscan2
- HSPA1A | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as rs777027010, COSV100989361; called by muse, mutect2, varscan2
- HSPA2 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770917203, COSV99904834; called by muse, mutect2, varscan2
- HSPA5 | c.1313C>A p.P438Q | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV99413332; called by muse, mutect2, varscan2
- HSPG2 | c.12328C>T p.R4110C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs766333633, COSV100760752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPG2 | c.10990C>T p.P3664S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65933954; called by muse, mutect2, varscan2
- HTR1A | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100108896, COSV100109021; called by muse, mutect2, varscan2
- HTR5A | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs866283043, COSV55280411; called by muse, mutect2, varscan2
- HTR5A | c.472T>A p.S158T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99839603; called by muse, mutect2, varscan2
- HTR7 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519305; called by mutect2, varscan2
- HTT | c.7848+2T>C p.X2616_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100750633; called by muse, mutect2, varscan2
- HUWE1 | c.2917A>G p.K973E | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99471557; called by muse, mutect2, varscan2
- HYAL1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782752459, COSV99807571; called by muse, mutect2, varscan2
- HYAL2 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100753858; called by muse, mutect2, varscan2
- HYOU1 | c.2974C>T p.R992W | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs1261295886, COSV101345551; called by muse, mutect2, varscan2
- IARS1 | c.56T>G p.L19W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100986799; called by muse, mutect2, varscan2
- IARS2 | c.1805A>T p.D602V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760151453, COSV100228226; called by muse, mutect2, varscan2
- IFI44 | c.608T>C p.F203S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV100877302; called by muse, mutect2, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs1202143274; called by mutect2, pindel, varscan2
- IFRD2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100269405; called by muse, mutect2, varscan2
- IFT122 | c.976A>G p.T326A (on ENST00000348417 / NM_052989.3; = p.T267A on NM_018262.4) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.754); catalogued as COSV99959082; called by muse, mutect2, varscan2
- IFT140 | c.938T>A p.L313Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101276328; called by muse, mutect2, varscan2
- IGF2R | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1392718372, COSV100807187; called by muse, mutect2
- IGFBPL1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs752454478, COSV66617767; called by muse, mutect2, varscan2
- IGHA1 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368728151; called by muse, mutect2, varscan2
- IGHA2 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782717196; called by muse, mutect2, varscan2
- IGSF10 | c.7726G>T p.E2576* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV56389036, COSV56401259; called by muse, mutect2, varscan2
- IGSF10 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as rs372971163; called by muse, mutect2, varscan2
- IGSF22 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100079496; called by muse, mutect2, varscan2
- IGSF3 | c.2800C>T p.R934W (on ENST00000369486 / NM_001007237.3; = p.R954W on NM_001542.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); catalogued as rs774101250, COSV100604471; called by mutect2, varscan2
- IGSF8 | c.479del p.P160Qfs*15 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs754902711; called by mutect2, pindel, varscan2
- IL16 | c.3088G>A p.E1030K (on ENST00000302987 / NM_172217.5; = p.E329K on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs369121994; called by muse, mutect2, varscan2
- IL17RC | c.1414C>T p.R472* (on ENST00000295981 / NM_153461.4; = p.R386* on NM_032732.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs772782362, COSV99925659; called by muse, mutect2, varscan2
- IL17RD | c.1550G>A p.G517D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99576891; called by muse, mutect2, varscan2
- IL18BP | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99474598; called by muse, mutect2, varscan2
- IL1R2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs759636734, COSV60206891; called by muse, mutect2, varscan2
- IL1RAP | c.1612T>C p.F538L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99299385; called by mutect2, varscan2
- IL36A | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV99382091; called by muse, mutect2, varscan2
- ILDR2 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99613597; called by muse, mutect2, varscan2
- ILVBL | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.436); catalogued as rs139501555; called by muse, mutect2, varscan2
- ILVBL | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1273852708, COSV54622774; called by muse, mutect2, varscan2
- INPP5B | c.2525G>A p.R842Q (on ENST00000373023; = p.R762Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs761903907, COSV65960638; called by muse, mutect2, varscan2
- INSC | c.1340T>C p.V447A | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.717); catalogued as COSV101088991; called by muse, mutect2
- INSYN2A | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 58/156 reads (37%) | catalogued as rs1223237561, COSV54730803; called by muse, mutect2, varscan2
- INTS8 | c.837del p.F279Lfs*6 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as COSV58249114; called by pindel, varscan2
- IPO4 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs571236753, COSV61018417; called by muse, mutect2, varscan2
- IPO9 | c.3118G>A p.G1040S | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV64233352; called by muse, mutect2
- IPPK | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.354); catalogued as COSV99845534; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs759821884; called by mutect2, varscan2
2,016 further variants in this file (1,334 protein-altering or splice-affecting, 620 silent, 62 other) are not listed here.
